Somatic mutation profile of tumor specimen TCGA-BJ-A0ZE-01A (aliquot TCGA-BJ-A0ZE-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0ZE, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 63.7 years (23,250 days).
Specimen TCGA-BJ-A0ZE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6251f7c8-207b-4594-ac66-32a2d13de7de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0ZE-10A (Blood Derived Normal), aliquot TCGA-BJ-A0ZE-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6135583d-03e0-4c16-aff6-b76c70ecde62

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Frame Shift Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 41/122 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.1714G>C p.E572Q (on ENST00000326195 / NM_001025091.2; = p.E534Q on NM_001090.3) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as COSV58230418; called by muse, mutect2, varscan2
- ADM | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV53403438; called by muse, mutect2, varscan2
- ATP2A2 | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as CD991621, COSV58046982; called by muse, mutect2, varscan2
- GPT | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs200853809, COSV52954519; called by muse, mutect2, varscan2
- KIAA0895L | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV51782454, COSV51783939; called by muse, mutect2, varscan2
- MEN1 | c.517del p.L173Wfs*17 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as CD1512198; called by mutect2, pindel, varscan2
- MITF | c.566A>G p.N189S (on ENST00000448226 / NM_006722.3; = p.N83S on NM_000248.4) | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.172); catalogued as COSV58835177; called by muse, mutect2, varscan2
- RPUSD1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.492); catalogued as rs1233851085, COSV50102081; called by muse, mutect2, varscan2
- SCN9A | c.5967G>C p.*1989Yext*23 (on ENST00000303354; = p.*1978Yext*23 on NM_002977.3) | Nonstop Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV57621212; called by muse, mutect2, varscan2
- SPATA31A1 | c.1721del p.P574Lfs*8 | Frame Shift Del (DEL) | VAF 21/205 reads (10%) | called by mutect2, pindel, varscan2
- ABCB7 | c.285T>C p.C95= (on ENST00000373394 / NM_001271696.3; = p.C96= on NM_004299.6) | Silent (SNP) | VAF 11/308 reads (4%) | catalogued as COSV53722797; called by muse, mutect2
- MFAP3L | c.480C>T p.A160= | Silent (SNP) | VAF 8/196 reads (4%) | catalogued as COSV64372907; called by muse, mutect2
- PLXNB3 | c.5040C>G p.R1680= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1557064793; called by muse, mutect2
- PRAMEF17 | c.852G>A p.L284= | Silent (SNP) | VAF 157/421 reads (37%) | called by muse, mutect2, varscan2
- SPATS2 | c.600A>G p.Q200= | Silent (SNP) | VAF 76/193 reads (39%) | catalogued as rs754948056, COSV58922534, COSV58924382; called by muse, mutect2, varscan2
